Somatic mutation profile of tumor specimen MBCProject_5094_T1_WES (aliquot MBCProject_5094_T1_WES_1) from CMI case MBCProject_5094, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_5094_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cb3eddb-783f-46ed-925f-4b6e4e1062e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_5094_SALIVA (Saliva), aliquot MBCProject_5094_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/912661f6-8a89-48cf-b44f-3aefe1b8657b

The open-access MAF lists 38 somatic variants for this specimen: 30 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 4, Intron 3, Nonsense Mutation 3, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 84/261 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL28A1 | c.2992C>T p.Q998* | Nonsense Mutation (SNP) | VAF 39/152 reads (26%) | catalogued as COSV68083519; called by muse, mutect2, varscan2
- FOXI3 | c.1244G>T p.R415L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs771597752; called by muse, mutect2, varscan2
- JADE2 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 73/279 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV50914175; called by muse, mutect2, varscan2
- PACRG | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1319040438, COSV61295273; called by muse, mutect2, varscan2
- PCDHA3 | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 173/623 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.508); catalogued as rs782568249; called by muse, mutect2, varscan2
- POM121L2 | c.2225C>A p.T742N | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV66277589; called by muse, mutect2, varscan2
- PRKAR1B | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV64319707; called by muse, mutect2, varscan2
- SULT2B1 | c.346C>T p.Q116* (on ENST00000201586 / NM_177973.2; = p.Q101* on NM_004605.2) | Nonsense Mutation (SNP) | VAF 64/998 reads (6%) | catalogued as rs780820646, COSV52374462; called by muse, mutect2
- SUPT16H | c.1878_1881del p.E627Yfs*19 | Frame Shift Del (DEL) | VAF 38/148 reads (26%) | catalogued as rs1566384325; called by mutect2, pindel, varscan2
- TNS4 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs140763191; called by muse, mutect2, varscan2
- ZNF480 | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 27/95 reads (28%) | catalogued as rs563704076, CM116868, COSV57994805; called by muse, mutect2, varscan2
- CARMIL2 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- CCT8L2 | c.670A>G p.I224V | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0.047); called by muse, mutect2
- CENPF | c.1207C>G p.Q403E | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- CNKSR3 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSRNP3 | c.1088G>A p.S363N | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ELOVL7 | c.490T>A p.F164I | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- GRIK2 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.953); called by muse, mutect2
- HSD17B14 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 40/558 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- KIAA0825 | c.3720G>A p.M1240I | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2
- KRT82 | c.699C>A p.F233L | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAP2K4 | c.673del p.I225Lfs*51 | Frame Shift Del (DEL) | VAF 34/136 reads (25%) | called by mutect2, pindel, varscan2
- PROCA1 | c.719A>C p.K240T (on ENST00000439862 / NM_001366301.1; = p.K212T on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- RGL3 | c.1276A>T p.T426S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SMARCA4 | c.3334A>G p.M1112V | Missense Mutation (SNP) | VAF 95/314 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SYNPO2L | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- UBASH3A | c.408C>A p.D136E | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- VPS54 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCA13 | c.8571C>T p.T2857= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs562649631, COSV71285385; called by muse, mutect2, varscan2
- NMT1 | c.300A>C p.S100= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- PRR12 | c.2085C>A p.P695= (on ENST00000615927; = p.P1516= on NM_020719.3) | Silent (SNP) | VAF 126/685 reads (18%) | called by muse, mutect2, varscan2
- TRPM4 | c.3636C>G p.S1212= | Silent (SNP) | VAF 106/563 reads (19%) | called by muse, mutect2, varscan2
- CCDC40 | c.2619+13C>G | Intron (SNP) | VAF 137/275 reads (50%) | called by muse, mutect2, varscan2
- GATA4 | c.*28G>T | 3'UTR (SNP) | VAF 49/153 reads (32%) | called by muse, mutect2, varscan2
- LHX6 | c.792+52G>A | Intron (SNP) | VAF 44/122 reads (36%) | catalogued as rs1291824569; called by muse, varscan2
- MOG | c.437-1485C>A | Intron (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
